Gene-level copy-number profile of tumor specimen TCGA-2Z-A9JK-01A from TCGA case TCGA-2Z-A9JK, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 50.8 years (18,540 days).
Specimen TCGA-2Z-A9JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.6a31f8aa-506b-4919-aeff-37ae7b0ad3c8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2Z-A9JK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ddfdb158-70ea-427d-ad3e-e0a7c9b48524

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,138; copy number 2: 52,182; copy number 3: 1,482; copy number 4: 8; copy number 5: 3; copy number 6: 1; copy number 8: 2; copy number 10: 1; copy number 17: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2Z-A9JK-01A-11D-A42I-01): tumor purity 0.48, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:66,042,500–66,050,718, 1 gene, copy number 10: PDE4B-AS1.
- chr5:45,890,216–45,895,970, 1 gene, copy number 5: AC122694.1.
- chr7:62,275,361–62,275,678, 1 gene, copy number 6: AC128676.1.
- chr8:43,672,823–43,674,591, 2 genes, copy number 17: AC139365.2, AC139365.1.
- chr11:21,260,061–21,284,955, 2 genes, copy number 5: AC090857.2, AC099730.1.
- chr11:50,409,042–50,422,316, 1 gene, copy number 8: AC024405.1.
- chr16:61,691,756–61,693,750, 1 gene, copy number 8: AC092125.1.

Autosomal genes at a single copy (total copy number 1): 3,723. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
